CCDI case PBBTAY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6f884bff-fac7-498e-81d8-830a730f771f

Demographics
Sex at birth: male.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,138 days).

Biospecimens (4 samples)
- Sample 0DGB91: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DGB9M, 0DGBAC (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGOAV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
